EXCEPTIONAL_RESPONDERS case ER-ABSE — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8428a433-3184-40a5-8d1a-f1ae61d3107a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Age at diagnosis: 59.9 years (21,888 days); Year of diagnosis: 2007; AJCC pathologic stage: Stage II; Prior malignancy: no; Days to last follow up: 2,782 days (7.6 years); Days to best overall response: 2,073 days (5.7 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Capecitabine + Irinotecan; Days to treatment start: 2,015 days (5.5 years).

Follow-up (1 entry)
- Days to follow up: 2,782 days (7.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,472 days (4.0 years); Days progression-free: 2,782 days (7.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABSE-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABSE-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 10; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide ER-ABSE-TTM1-A-1-0-S2: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 10; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
